Somatic mutation profile of tumor specimen TCGA-2J-AABF-01A (aliquot TCGA-2J-AABF-01A-31D-A40W-08) from TCGA case TCGA-2J-AABF, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.7 years (26,936 days).
Specimen TCGA-2J-AABF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 200b6d0f-8215-4fc8-8b82-fc797c1150d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2J-AABF-10A (Blood Derived Normal), aliquot TCGA-2J-AABF-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2c40992-dc28-4e16-8fb4-f533a074f810

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 13, Nonsense Mutation 4, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 22/94 reads (23%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/249 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.726C>A p.C242* | Nonsense Mutation (SNP) | VAF 38/214 reads (18%) | hotspot (GDC flag); catalogued as CM102354, COSV52677195, COSV52704436, COSV53034631; called by muse, mutect2, varscan2
- TPO | c.1804C>T p.R602C | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs372225161; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABTB2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as rs765150693, COSV54391324; called by muse, mutect2
- APC | c.3755C>A p.S1252Y | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57333121; called by muse, mutect2
- ASGR2 | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV99643071; called by muse, mutect2
- CADPS2 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.02); catalogued as COSV100463812; called by muse, mutect2
- CD1D | c.986+1G>A p.X329_splice | Splice Site (SNP) | VAF 46/548 reads (8%) | catalogued as rs775899867, COSV63808409; called by muse, mutect2
- CDC25B | c.1517G>A p.R506H (on ENST00000245960 / NM_021873.3; = p.R492H on NM_004358.4) | Missense Mutation (SNP) | VAF 125/776 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99848062; called by muse, mutect2, varscan2
- CEP290 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100469095; called by muse, mutect2, varscan2
- CHRNA2 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 16/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs1060503072, COSV99532351; ClinVar: uncertain significance; called by muse, mutect2
- CNBD1 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 38/428 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101575292; called by muse, mutect2
- CTNNA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768529296, COSV63553496, COSV63606300; called by muse, mutect2, varscan2
- DNAAF5 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 72/849 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52415540; called by muse, mutect2
- E2F8 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 61/378 reads (16%) | catalogued as rs562160670, COSV51461947; called by muse, mutect2, varscan2
- FTSJ3 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 27/379 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100037348; called by muse, mutect2
- KCNB2 | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 23/430 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV73048998, COSV73050348; called by muse, mutect2
- KIAA1755 | c.1660A>G p.T554A | Missense Mutation (SNP) | VAF 17/314 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99642290; called by muse, mutect2
- MAP6 | c.1838C>T p.P613L | Missense Mutation (SNP) | VAF 47/568 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100496790; called by muse, mutect2
- NAA60 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 19/283 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100692828, COSV62654672; called by muse, mutect2
- NFS1 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 18/233 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs188144557, COSV65054350; called by muse, mutect2
- PDE3A | c.1535G>A p.R512Q | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs185449585, COSV62982228; called by muse, mutect2
- PEG10 | c.506G>A p.R169H (on ENST00000482108 / NM_001040152.2; = p.R203H on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/651 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as COSV101509924, COSV71788589; called by muse, mutect2, varscan2
- PIKFYVE | c.2891C>T p.P964L | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.017); catalogued as rs753891473, COSV52249017; called by muse, mutect2
- PLEKHA5 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 29/269 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100164324; called by muse, mutect2, varscan2
- RFPL1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.945); catalogued as rs577925684, COSV100585803; called by muse, mutect2
- SIGLEC8 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 30/660 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as rs200631849, COSV58471811; called by muse, mutect2
- SLC41A3 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 30/390 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.088); catalogued as rs138712564; called by muse, mutect2
- TARS3 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs146271638; called by muse, mutect2
- TBC1D2B | c.2153T>A p.L718Q | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317437; called by muse, mutect2
- TIMM44 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs1201351937, COSV99564168; called by muse, mutect2, varscan2
- TRDN | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV100522505, COSV62123020; called by muse, mutect2
- TTN | c.21370C>T p.R7124* (on ENST00000591111; = p.R6197* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 47/343 reads (14%) | catalogued as rs746136883, COSV59870609; called by muse, mutect2, varscan2
- USP5 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 47/812 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs781900287, COSV99978806; called by muse, mutect2
- ZNF182 | c.1785G>C p.E595D | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV100527109, COSV59357035; called by muse, mutect2, varscan2
- ZNF470 | c.1250G>T p.R417I | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs1285721807, COSV57967696, COSV57970876; called by muse, mutect2
- GRHL2 | c.1510_1511insTCTC p.R504Lfs*10 | Frame Shift Ins (INS) | VAF 50/439 reads (11%) | called by mutect2, pindel
- DIDO1 | c.6144C>T p.S2048= | Silent (SNP) | VAF 29/416 reads (7%) | catalogued as rs760919841, COSV56634228; called by muse, mutect2
- FAH | c.780T>A p.S260= | Silent (SNP) | VAF 73/377 reads (19%) | catalogued as COSV99930376; called by muse, mutect2, varscan2
- GABRB1 | c.1197C>T p.S399= | Silent (SNP) | VAF 23/209 reads (11%) | catalogued as COSV99782214; called by muse, mutect2, varscan2
- GRIK3 | c.423G>T p.P141= | Silent (SNP) | VAF 32/254 reads (13%) | catalogued as COSV100902148; called by muse, mutect2, varscan2
- MLXIPL | c.2271C>T p.Y757= | Silent (SNP) | VAF 15/175 reads (9%) | catalogued as rs781875960, COSV100515422; called by muse, mutect2
- NTSR1 | c.447C>T p.D149= | Silent (SNP) | VAF 19/303 reads (6%) | catalogued as rs1167999314, COSV100980669; called by muse, mutect2
- RARG | c.789C>T p.L263= | Silent (SNP) | VAF 86/1288 reads (7%) | catalogued as COSV58433665, COSV58434837; called by muse, mutect2
- SCN9A | c.189T>C p.Y63= | Silent (SNP) | VAF 20/262 reads (8%) | catalogued as rs1306352696, COSV100313345; called by muse, mutect2
- SLC25A38 | c.105C>T p.S35= | Silent (SNP) | VAF 22/376 reads (6%) | catalogued as COSV99827875; called by muse, mutect2
- SPEG | c.1080G>A p.S360= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV56675801; called by muse, mutect2
- TBC1D32 | c.2316C>T p.T772= | Silent (SNP) | VAF 96/621 reads (15%) | catalogued as COSV99250641; called by muse, mutect2, varscan2
- UBR4 | c.2268G>A p.V756= | Silent (SNP) | VAF 70/495 reads (14%) | catalogued as COSV100921229; called by muse, mutect2, varscan2
- VAX1 | c.420C>T p.S140= | Silent (SNP) | VAF 19/167 reads (11%) | catalogued as rs775686724, COSV53331359; called by muse, mutect2, varscan2
- CORT | c.-146A>C | 5'UTR (SNP) | VAF 60/781 reads (8%) | catalogued as COSV100259227; called by muse, mutect2
